Somatic mutation profile of tumor specimen C3N-04168-01 (aliquot CPT0251530006) from CPTAC case C3N-04168, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 51.3 years (18,727 days).
Specimen C3N-04168-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01c2df8d-43e5-41a5-92df-e3a7a898fc7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04168-71 (Blood Derived Normal), aliquot CPT0255960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90d59b8d-3ac5-4f6b-9cac-fa391eac8b20

The open-access MAF lists 28 somatic variants for this specimen: 13 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 9, Intron 2, 3'Flank 2, 3'UTR 2, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.1575-1G>C p.X525_splice | Splice Site (SNP) | VAF 16/389 reads (4%) | catalogued as CS961644, CS982294, COSV58520503, COSV58526843; called by muse, mutect2
- NR3C2 | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); catalogued as rs1367228054; called by muse, mutect2
- PAX6 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs372143889, CD097097; called by muse, mutect2
- SLC25A20 | c.529A>T p.M177L | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1397431446, COSV59803615; called by muse, mutect2
- ZNF721 | c.2336C>T p.T779M (on ENST00000338977; = p.T791M on NM_133474.4) | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs782648764, COSV59089657; called by muse, mutect2
- CCDC110 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- CHML | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 9/280 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- IPO4 | c.2497G>C p.E833Q | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- MRPL4 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2
- PRICKLE2 | c.387C>G p.I129M (on ENST00000295902; = p.I73M on NM_198859.4) | Missense Mutation (SNP) | VAF 23/412 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM34 | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- SLC4A3 | c.935_936insGAC p.K312_K313insT | In Frame Ins (INS) | VAF 9/82 reads (11%) | called by mutect2, varscan2
- TTN | c.45788C>G p.S15263C (on ENST00000591111; = p.S7839C on NM_003319.4) | Missense Mutation (SNP) | VAF 12/401 reads (3%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD33B | c.849C>A p.L283= | Silent (SNP) | VAF 17/430 reads (4%) | called by muse, mutect2
- BBS9 | c.2269C>T p.L757= (on ENST00000242067 / NM_001348036.1; = p.L717= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/242 reads (3%) | catalogued as COSV54167564, COSV54171808; called by muse, mutect2
- EGFR | c.3504C>T p.D1168= | Silent (SNP) | VAF 22/456 reads (5%) | called by muse, mutect2
- IGDCC4 | c.1299G>A p.T433= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV61537879; called by muse, mutect2
- OLFML3 | c.576C>T p.A192= | Silent (SNP) | VAF 9/254 reads (4%) | called by muse, mutect2
- SLC9A4 | c.927C>T p.F309= | Silent (SNP) | VAF 7/194 reads (4%) | called by muse, mutect2
- TRPC4AP | c.1551T>G p.R517= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV99328918; called by muse, mutect2
- USH2A | c.6912C>T p.F2304= | Silent (SNP) | VAF 15/277 reads (5%) | catalogued as COSV56365386; called by muse, mutect2
- XKR8 | c.612C>T p.F204= | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as rs760628091; called by muse, mutect2
- AL353804.6 | chrX:73827581 G>A | 3'Flank (SNP) | VAF 28/764 reads (4%) | catalogued as rs1314231956; called by muse, mutect2
- CYP4B1 | c.368-312C>T | Intron (SNP) | VAF 14/226 reads (6%) | catalogued as rs769375737; called by muse, mutect2
- MPV17L2 | c.*56G>A | 3'UTR (SNP) | VAF 15/316 reads (5%) | called by muse, mutect2
- PCDHB6 | chr5:141157171 C>T | 3'Flank (SNP) | VAF 28/409 reads (7%) | catalogued as rs1391090642; called by muse, mutect2
- RDX | c.1748+11T>C | Intron (SNP) | VAF 19/312 reads (6%) | called by muse, mutect2
- SLC25A13 | c.*163C>T | 3'UTR (SNP) | VAF 15/501 reads (3%) | called by muse, mutect2
